Somatic mutation profile of tumor specimen ER-ADIN-TTM1-A (aliquot ER-ADIN-TTM1-A-1-0-D-A514-34) from EXCEPTIONAL_RESPONDERS case ER-ADIN, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IVB; Age at diagnosis: 54.1 years (19,760 days).
Specimen ER-ADIN-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb340131-baff-4dba-999e-ee05f91bbf8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-ADIN-NT1-A (Solid Tissue Normal), aliquot ER-ADIN-NT1-A-1-0-D-A514-34; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc8a82f7-f58e-4929-b53e-469b95d0e01d

The open-access MAF lists 62 somatic variants for this specimen: 46 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 13, Frame Shift Del 6, Splice Site 2, Nonsense Mutation 2, 3'UTR 1, 5'Flank 1, In Frame Del 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 101/257 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1678G>T p.D560Y (on ENST00000521381 / NM_181523.3; = p.D290Y on NM_181504.4) | Missense Mutation (SNP) | VAF 40/191 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057519839, COSV57123942, COSV57127598, COSV57130158; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 94/177 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC109583.1 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs763693848, COSV59350388; called by muse, mutect2, varscan2
- ASCL4 | c.190G>A p.V64M | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs754138406; called by muse, mutect2, varscan2
- BCL11B | c.1651C>T p.R551W (on ENST00000357195 / NM_001282237.2; = p.R480W on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV61734760; called by muse, mutect2, varscan2
- CATSPERE | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs371932318; called by muse, mutect2, varscan2
- CIAO2A | c.445C>G p.R149G | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); catalogued as rs746761595, COSV55539373; called by muse, mutect2, varscan2
- CSMD2 | c.9689G>A p.R3230H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1343666692, COSV99594435; called by muse, mutect2, varscan2
- DIAPH3 | c.2191C>T p.R731W (on ENST00000400324 / NM_001042517.2; = p.R468W on NM_030932.3) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771964464, COSV99934075; called by muse, varscan2
- DMD | c.2531del p.Q844Rfs*2 | Frame Shift Del (DEL) | VAF 30/178 reads (17%) | catalogued as COSV100819727; called by mutect2, pindel, varscan2
- GABRG2 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62716101, COSV62720867; called by muse, mutect2, varscan2
- GALNT14 | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs374361605; called by muse, mutect2, varscan2
- GJB3 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs759759043, COSV64904378; called by muse, mutect2, varscan2
- ING1 | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 30/151 reads (20%) | catalogued as COSV58167057; called by muse, mutect2, varscan2
- LRRC43 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as rs369545625; called by muse, mutect2, varscan2
- LYPD3 | c.193G>T p.V65L | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV54989350; called by muse, mutect2, varscan2
- MDH1B | c.180G>C p.K60N | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV65588841, COSV65589822; called by muse, mutect2, varscan2
- RNF216 | c.1283_1285del p.K428del (on ENST00000425013 / NM_207116.3; = p.K485del on NM_207111.4) | In Frame Del (DEL) | VAF 14/97 reads (14%) | catalogued as rs1275563847; called by pindel, varscan2
- SEZ6L2 | c.1129C>T p.R377C (on ENST00000308713 / NM_001114099.3; = p.R307C on NM_012410.4) | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs752385379, COSV58102018; called by muse, mutect2, varscan2
- SIPA1L2 | c.2119G>A p.V707I | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs368842985; called by muse, mutect2, varscan2
- SLC26A1 | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs754987516, COSV56102314; called by muse, mutect2, varscan2
- TRPV5 | c.1165G>T p.E389* | Nonsense Mutation (SNP) | VAF 15/81 reads (19%) | catalogued as COSV54687358; called by muse, mutect2, varscan2
- ADGRG6 | c.2294T>C p.L765S | Missense Mutation (SNP) | VAF 10/294 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARID1A | c.2460del p.N820Kfs*13 | Frame Shift Del (DEL) | VAF 22/85 reads (26%) | called by mutect2, pindel, varscan2
- CDC14A | c.837del p.A280Lfs*9 | Frame Shift Del (DEL) | VAF 17/76 reads (22%) | called by mutect2, pindel, varscan2
- CFAP161 | c.627C>A p.F209L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPG5 | c.8A>C p.E3A | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HS3ST3B1 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL1R1 | c.569A>G p.H190R | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- KRTDAP | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.925); called by muse, mutect2
- LRRK2 | c.1834T>A p.Y612N | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- LSM14B | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- MAPKAPK3 | c.1009A>C p.S337R | Missense Mutation (SNP) | VAF 39/236 reads (17%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- NINJ2 | c.329T>C p.I110T | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- NKX1-2 | c.306del p.L103Cfs*12 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | called by mutect2, pindel, varscan2
- NME7 | c.820-1G>T p.X274_splice | Splice Site (SNP) | VAF 20/73 reads (27%) | called by muse, mutect2, varscan2
- PAPSS1 | c.1154A>T p.D385V | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- REXO1 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF212 | c.796C>G p.P266A | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- RTCA | c.999+2_999+21del p.X333_splice | Splice Site (DEL) | VAF 10/60 reads (17%) | called by mutect2, pindel
- TRPC3 | c.722C>T p.A241V (on ENST00000379645 / NM_001366479.2; = p.A168V on NM_003305.2) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TSC2 | c.5008dup p.H1670Pfs*36 | Frame Shift Ins (INS) | VAF 24/117 reads (21%) | called by mutect2, pindel, varscan2
- USF3 | c.5841_5854del p.R1948Tfs*19 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.7593G>C p.R2531S | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- ZNFX1 | c.4974_4990del p.T1659* | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel, varscan2
- CHAC1 | c.123G>A p.L41= | Silent (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- CRAT | c.1558C>T p.L520= | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
- DBX1 | c.288G>A p.P96= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as rs745307504; called by muse, mutect2, varscan2
- DENND2C | c.555C>T p.Y185= | Silent (SNP) | VAF 45/182 reads (25%) | catalogued as rs374406910; called by muse, mutect2, varscan2
- DSP | c.4563G>A p.A1521= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as rs774258993; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM83G | c.606C>T p.A202= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs778229006; called by muse, mutect2, varscan2
- FTHL17 | c.9C>T p.T3= | Silent (SNP) | VAF 52/192 reads (27%) | catalogued as rs774744538, COSV63266625; called by muse, mutect2, varscan2
- MAML2 | c.1956A>G p.Q652= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs894365688; called by muse, varscan2
- NINL | c.357C>T p.D119= | Silent (SNP) | VAF 24/118 reads (20%) | catalogued as rs192263998; called by muse, mutect2, varscan2
- PCDHA12 | c.1068G>A p.S356= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs1245489112, COSV56532757, COSV56541754; called by muse, mutect2, varscan2
- ROBO1 | c.4593G>A p.G1531= | Silent (SNP) | VAF 55/200 reads (28%) | called by muse, mutect2, varscan2
- SLC15A1 | c.174G>A p.T58= | Silent (SNP) | VAF 26/138 reads (19%) | catalogued as rs370610278, COSV64712900; called by muse, mutect2, varscan2
- ZNF668 | c.786G>A p.T262= | Silent (SNP) | VAF 30/126 reads (24%) | catalogued as rs1466498649, COSV56216290; called by muse, mutect2, varscan2
- MIR1270 | chr19:20397999 G>A | 3'Flank (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- NIFK | chr2:121737139 del CGCGCGGAGGCGC | 5'Flank (DEL) | VAF 8/55 reads (15%) | called by mutect2, pindel
- SOX11 | c.*733C>T | 3'UTR (SNP) | VAF 14/67 reads (21%) | called by muse, mutect2, varscan2
